Somatic mutation profile of tumor specimen TCGA-BJ-A28V-01A (aliquot TCGA-BJ-A28V-01A-11D-A19J-08) from TCGA case TCGA-BJ-A28V, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 80.8 years (29,508 days).
Specimen TCGA-BJ-A28V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2f06452-9912-4f36-99bb-e9a90d34d2e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A28V-10A (Blood Derived Normal), aliquot TCGA-BJ-A28V-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98068fe7-cb62-41ed-9af1-314fa1143fc4

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADO | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV65678190; called by muse, mutect2, varscan2
- DCLRE1C | c.1561C>T p.L521F (on ENST00000378278 / NM_001350965.2; = p.L406F on NM_022487.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); catalogued as COSV57955034; called by muse, mutect2, varscan2
- DOK5 | c.921A>T p.*307Cext*2 | Nonstop Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV52823583; called by muse, mutect2
- FUT3 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54607405; called by muse, mutect2, varscan2
- JAK1 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV61094750; called by muse, mutect2, varscan2
- MYH3 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56868289; called by muse, mutect2, varscan2
- NUP210L | c.4669T>A p.S1557T | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.492); catalogued as COSV55154065; called by muse, mutect2, varscan2
- OR10AG1 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1464346525, COSV56634129; called by muse, mutect2, varscan2
- OR4M1 | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV60062827; called by muse, mutect2, varscan2
- PCNX2 | c.4739T>A p.I1580N | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV50846502; called by muse, mutect2, varscan2
- PLEKHA5 | c.2420A>G p.Y807C | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs746003413, COSV54697113; called by muse, mutect2, varscan2
- PXMP2 | c.229del p.V77Ffs*10 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as COSV57690958, COSV57692706; called by mutect2, pindel, varscan2
- SULT2A1 | c.136+1G>A p.X46_splice | Splice Site (SNP) | VAF 32/208 reads (15%) | catalogued as rs779671480, COSV99705521; called by muse, mutect2, varscan2
- TBX18 | c.1538C>G p.T513S | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV63737634; called by muse, mutect2, varscan2
- TKTL2 | c.594T>G p.H198Q | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV54920573; called by muse, mutect2, varscan2
- CD46 | c.592_607del p.D198Lfs*30 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- MRC1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- NSD1 | c.7183dup p.T2395Nfs*2 | Frame Shift Ins (INS) | VAF 36/115 reads (31%) | called by mutect2, pindel, varscan2
- GUCY2C | c.534C>T p.N178= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs762059100, COSV53793850; called by muse, mutect2, varscan2
- HEG1 | c.903C>T p.D301= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV60764366; called by muse, mutect2
- KIF4B | c.384A>G p.K128= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as rs1439422015, COSV70530678; called by muse, mutect2, varscan2
- USP48 | c.147A>G p.K49= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV57612887; called by muse, mutect2, varscan2
